TARGET case TARGET-50-PAKXXF — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2702f0ce-d496-50cd-b4f9-ee82d0e8eb70

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 416 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 5.0 years (1,821 days); Year of diagnosis: 2001; Days to last follow up: 416 days (1.1 years); Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis; Wilms tumor histologic subtype: Unfavorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 333 days; Days to first event: 333 days; First event: Relapse.
- Days to follow up: 416 days (1.1 years); Year of follow up: 2002.

Biospecimens (2 samples)
- Sample TARGET-50-PAKXXF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-50-PAKXXF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 416
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: DAWT

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAKXXF-01A:
- Histological Subtype: anaplastic Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: Yes
- % Tumor Nuclei: Top: 90
- % Non tumor Nuclei: Top: 10
- % Cellular Tumor: Top: 90
- % Normal: Top: 0
- % Stroma: Top: 10
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 90
- % Non tumor Nuclei: Bottom: 10
- % Cellular Tumor: Bottom: 90
- % Normal: Bottom: 0
- % Stroma: Bottom: 10
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: Pass

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAKXXF-11A:
- Histological Subtype: anaplastic Wilms
- Specimen Type: normal solid tissue
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 95
- % Non tumor Nuclei: Top: 5
- % Cellular Tumor: Top: 100
- % Normal: Top: 0
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 95
- % Non tumor Nuclei: Bottom: 5
- % Cellular Tumor: Bottom: 100
- % Normal: Bottom: 0
- % Stroma: Bottom: 0
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: fail
